Somatic mutation profile of tumor specimen TARGET-40-PANFZN-01A (aliquot TARGET-40-PANFZN-01A-01D) from TARGET case TARGET-40-PANFZN, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.8 years (5,767 days).
Specimen TARGET-40-PANFZN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb5f4843-52f1-4692-91a4-a2199813916b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANFZN-10A (Blood Derived Normal), aliquot TARGET-40-PANFZN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87397284-b2c4-4b8d-8a8e-47331aa6a5ff

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIPAP1 | c.1340A>G p.H447R | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM186A | c.3294G>T p.T1098= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as rs1338401841; called by muse, varscan2
- SLC4A8 | c.492C>T p.H164= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
